Somatic mutation profile of tumor specimen TCGA-AF-6672-01A (aliquot TCGA-AF-6672-01A-11D-1826-10) from TCGA case TCGA-AF-6672, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IV; Age at diagnosis: 43.7 years (15,965 days).
Specimen TCGA-AF-6672-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e0387067-62d0-4db6-8af3-9586ade68a66.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AF-6672-10A (Blood Derived Normal), aliquot TCGA-AF-6672-10A-01D-1826-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c51642ba-9e2c-4acb-a1f9-c2ccd7ab2707

The open-access MAF lists 85 somatic variants for this specimen: 64 protein-altering or splice-affecting, 18 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 18, Nonsense Mutation 3, Splice Region 2, Frame Shift Ins 2, Intron 1, Splice Site 1, Frame Shift Del 1, 5'UTR 1, In Frame Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 124/185 reads (67%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 25/105 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.583A>T p.I195F | Missense Mutation (SNP) | VAF 27/68 reads (40%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs942158624, COSV52677568, COSV52809310, COSV53233300; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCD2 | c.412A>C p.K138Q | Missense Mutation (SNP) | VAF 74/125 reads (59%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.98); catalogued as COSV58051898; called by muse, mutect2, varscan2
- ADAMTSL1 | c.3329G>A p.R1110H | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1299556145, COSV65892344; called by muse, mutect2, varscan2
- ADCY8 | c.3736G>A p.D1246N | Missense Mutation (SNP) | VAF 46/98 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.091); catalogued as rs775562104, COSV53908119; called by mutect2, varscan2
- ANKRD30A | c.2034G>T p.K678N (on ENST00000611781; = p.K622N on NM_052997.2) | Missense Mutation (SNP) | VAF 75/293 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.775); catalogued as COSV64610428, COSV64624442; called by muse, mutect2, varscan2
- APOL4 | c.810T>A p.N270K (on ENST00000352371 / NM_145660.2; = p.N267K on NM_030643.4) | Missense Mutation (SNP) | VAF 5/20 reads (25%) | SIFT tolerated (0.9); PolyPhen benign (0.034); catalogued as rs1569531008, COSV100274139; called by muse, mutect2, varscan2
- ARHGEF7 | c.961G>A p.E321K (on ENST00000375741 / NM_001113511.2; = p.E143K on NM_003899.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 50/120 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.961); catalogued as COSV54543449; called by muse, mutect2, varscan2
- ATPSCKMT | c.545G>A p.R182Q | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.14); PolyPhen benign (0.121); catalogued as rs371836379; called by muse, mutect2
- CORIN | c.63G>A p.P21= | Splice Region (SNP) | VAF 3/23 reads (13%) | catalogued as rs1350872011, COSV56701157; called by muse, varscan2
- CRMP1 | c.1623A>C p.L541F | Missense Mutation (SNP) | VAF 68/104 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.295); catalogued as rs1205078406, COSV61480268; called by muse, mutect2
- CRMP1 | c.1621T>A p.L541I | Missense Mutation (SNP) | VAF 70/108 reads (65%) | SIFT tolerated (0.16); PolyPhen benign (0.323); catalogued as COSV61480278; called by muse, mutect2
- CSMD1 | c.5888G>A p.R1963H (on ENST00000520002; = p.R1962H on NM_033225.6) | Missense Mutation (SNP) | VAF 35/62 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1057015722, COSV59325348; called by muse, mutect2, varscan2
- DPP10 | c.1280A>T p.K427M | Missense Mutation (SNP) | VAF 15/130 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.269); catalogued as COSV59686944; called by muse, mutect2, varscan2
- EPHB1 | c.2071C>T p.R691W | Missense Mutation (SNP) | VAF 60/161 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs767340477, COSV67661665; called by muse, mutect2, varscan2
- FAM155A | c.1232G>C p.R411T | Missense Mutation (SNP) | VAF 57/152 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65562322; called by muse, mutect2, varscan2
- FIGN | c.1667T>A p.V556D | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60766717; called by muse, mutect2, varscan2
- FRAS1 | c.130G>A p.D44N | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs568676550, COSV53611295; called by muse, mutect2, varscan2
- GPR4 | c.1043C>A p.S348Y | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT deleterious (0.04); PolyPhen benign (0.085); catalogued as COSV59917054; called by muse, mutect2, varscan2
- GSTM4 | c.456+1G>T p.X152_splice | Splice Site (SNP) | VAF 67/236 reads (28%) | catalogued as COSV58694631; called by muse, mutect2, varscan2
- INPP5K | c.112C>A p.L38M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV57441061; called by muse, mutect2, varscan2
- KCNT2 | c.1133C>A p.A378D | Missense Mutation (SNP) | VAF 15/314 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99654718; called by muse, mutect2
- LENG8 | c.794C>T p.P265L | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.05); PolyPhen benign (0.212); catalogued as COSV58727768; called by muse, mutect2, varscan2
- LINS1 | c.1815G>A p.M605I | Missense Mutation (SNP) | VAF 21/67 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.001); catalogued as COSV59078927; called by muse, mutect2, varscan2
- LRP1B | c.3802C>G p.H1268D | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101257926; called by muse, mutect2, varscan2
- MED12 | c.440C>G p.A147G | Missense Mutation (SNP) | VAF 32/76 reads (42%) | SIFT tolerated (0.05); PolyPhen benign (0.407); catalogued as COSV61340179; called by muse, mutect2, varscan2
- MEIS2 | c.827G>A p.R276H (on ENST00000561208 / NM_170675.5; = p.R263H on NM_002399.3) | Missense Mutation (SNP) | VAF 49/141 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.005); catalogued as rs767585793, COSV54933573, COSV54944315; called by muse, mutect2, varscan2
- MYOM1 | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 12/78 reads (15%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.999); catalogued as rs371246473; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- NEB | c.18664A>G p.T6222A | Missense Mutation (SNP) | VAF 36/76 reads (47%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.452); catalogued as COSV51417617; called by muse, mutect2, varscan2
- NEB | c.14930G>A p.R4977H | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs1487589344, COSV51417622; called by muse, mutect2, varscan2
- ODF3L2 | c.746C>T p.T249I | Missense Mutation (SNP) | VAF 35/73 reads (48%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.899); catalogued as COSV52744121; called by muse, mutect2, varscan2
- OR10J5 | c.449G>A p.G150D | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.589); catalogued as COSV58386102; called by muse, mutect2, varscan2
- OR4S1 | c.767A>G p.Y256C | Missense Mutation (SNP) | VAF 53/136 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60679139; called by muse, mutect2, varscan2
- PCDH11X | c.2624A>C p.K875T | Missense Mutation (SNP) | VAF 102/239 reads (43%) | SIFT tolerated (0.14); PolyPhen benign (0.085); catalogued as COSV100012697; called by muse, mutect2, varscan2
- PDZD8 | c.1709_1720del p.S570_D574delinsY | In Frame Del (DEL) | VAF 60/239 reads (25%) | catalogued as COSV57825633; called by mutect2, pindel, varscan2
- PRDX6 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 84/162 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.506); catalogued as COSV61165537; called by muse, mutect2, varscan2
- PRRG1 | c.485G>A p.R162H | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.451); catalogued as rs782128331, COSV66157633; called by muse, mutect2, varscan2
- PTPN13 | c.7176C>G p.I2392M (on ENST00000411767 / NM_080683.3; = p.I2373M on NM_006264.3) | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57407852; called by muse, mutect2, varscan2
- PTPRZ1 | c.856C>T p.R286* | Nonsense Mutation (SNP) | VAF 45/80 reads (56%) | catalogued as rs771283585, COSV66436171, COSV66436709; called by muse, mutect2, varscan2
- PUM1 | c.1676A>G p.Y559C | Missense Mutation (SNP) | VAF 22/55 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as rs777219058, COSV57085561; called by muse, mutect2, varscan2
- RAI14 | c.2911A>G p.T971A | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.192); catalogued as COSV99463643; called by muse, mutect2, varscan2
- RIMS1 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 13/70 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.944); catalogued as rs771037675, COSV53462859; called by muse, mutect2, varscan2
- ROBO2 | c.3127G>C p.G1043R | Missense Mutation (SNP) | VAF 50/143 reads (35%) | SIFT tolerated (0.35); PolyPhen benign (0.243); catalogued as COSV59911836; called by muse, mutect2, varscan2
- RSRC1 | c.96T>A p.S32R | Missense Mutation (SNP) | VAF 97/245 reads (40%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.112); catalogued as COSV55828956; called by muse, mutect2, varscan2
- SEL1L2 | c.27G>C p.E9D | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT tolerated, low confidence (0.88); PolyPhen benign (0); catalogued as COSV53152343; called by muse, mutect2, varscan2
- SEMA3C | c.4G>A p.A2T | Missense Mutation (SNP) | VAF 5/45 reads (11%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0); catalogued as COSV99543228; called by muse, mutect2, varscan2
- SMAD4 | c.1224T>A p.F408L | Missense Mutation (SNP) | VAF 16/29 reads (55%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV61688439; called by muse, mutect2, varscan2
- SORCS2 | c.1992C>T p.G664= | Splice Region (SNP) | VAF 7/26 reads (27%) | catalogued as rs540252369, COSV100212902; called by muse, mutect2, varscan2
- STAG3 | c.2800C>G p.Q934E | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.277); catalogued as COSV57930529; called by muse, mutect2, varscan2
- STIM1 | c.895C>T p.R299W | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779075210, COSV56154784; called by muse, mutect2, varscan2
- STXBP5 | c.1042C>G p.L348V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.57); PolyPhen probably damaging (0.962); catalogued as COSV51652197; called by muse, mutect2, varscan2
- SYNE1 | c.6013C>T p.R2005* (on ENST00000367255 / NM_182961.4; = p.R2012* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 68/125 reads (54%) | catalogued as rs200119679, COSV54994168, COSV55065630; called by muse, mutect2, varscan2
- TG | c.1535G>C p.G512A | Missense Mutation (SNP) | VAF 13/67 reads (19%) | SIFT tolerated (0.11); PolyPhen benign (0.079); catalogued as rs1425080150, COSV55076404; called by muse, mutect2, varscan2
- TGM7 | c.1501G>A p.E501K | Missense Mutation (SNP) | VAF 13/21 reads (62%) | SIFT tolerated (0.91); PolyPhen benign (0.028); catalogued as rs751308253, COSV71772722; called by muse, mutect2, varscan2
- TMEM94 | c.1396C>T p.R466* | Nonsense Mutation (SNP) | VAF 21/54 reads (39%) | catalogued as rs777469062, COSV58594989, COSV58601566; called by muse, mutect2, varscan2
- TMPRSS11A | c.416T>A p.I139N | Missense Mutation (SNP) | VAF 115/242 reads (48%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.979); catalogued as COSV58358471; called by muse, mutect2, varscan2
- VPS33B | c.1754G>A p.R585Q | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.993); catalogued as rs147814686; called by muse, mutect2, varscan2
- ZNF180 | c.883C>A p.H295N | Missense Mutation (SNP) | VAF 43/88 reads (49%) | SIFT tolerated (0.07); PolyPhen benign (0.22); catalogued as rs1298892106, COSV55425198, COSV55425681; called by muse, mutect2, varscan2
- ZNF81 | c.958T>C p.Y320H | Missense Mutation (SNP) | VAF 57/67 reads (85%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV58576288; called by muse, mutect2, varscan2
- ZSCAN31 | c.116G>A p.R39Q | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.211); catalogued as rs766378752, COSV60180329; called by muse, mutect2
- AMPD1 | c.433_445del p.V145Rfs*60 | Frame Shift Del (DEL) | VAF 45/100 reads (45%) | called by mutect2, pindel, varscan2
- CFAP61 | c.2150dup p.L717Ffs*8 | Frame Shift Ins (INS) | VAF 31/192 reads (16%) | called by mutect2, pindel, varscan2
- TMEM181 | c.232dup p.R78Kfs*4 | Frame Shift Ins (INS) | VAF 18/123 reads (15%) | called by mutect2, pindel, varscan2
- ADGRA1 | c.378G>A p.P126= | Silent (SNP) | VAF 3/11 reads (27%) | catalogued as rs368145789; called by muse, mutect2
- ALPI | c.528C>T p.A176= | Silent (SNP) | VAF 18/73 reads (25%) | catalogued as rs780862777, COSV55014617; called by muse, mutect2, varscan2
- BAHD1 | c.996C>T p.G332= | Silent (SNP) | VAF 10/31 reads (32%) | catalogued as rs534764286, COSV69083978; called by muse, mutect2, varscan2
- BBS9 | c.1230C>T p.D410= | Silent (SNP) | VAF 36/74 reads (49%) | catalogued as rs915003834, COSV99628818; called by muse, mutect2, varscan2
- BRSK2 | c.873G>A p.S291= | Silent (SNP) | VAF 19/55 reads (35%) | catalogued as rs765211865, COSV57543182; called by muse, mutect2, varscan2
- CBWD1 | c.1062A>G p.T354= | Silent (SNP) | VAF 55/321 reads (17%) | catalogued as COSV100071029; called by muse, mutect2, varscan2
- CUX2 | c.339C>T p.D113= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs760583393, COSV55632352; called by muse, mutect2, varscan2
- FNDC7 | c.1272G>A p.S424= | Silent (SNP) | VAF 66/131 reads (50%) | catalogued as rs777246094, COSV54753726; called by muse, mutect2, varscan2
- HDAC11 | c.468G>A p.A156= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as rs140627816, COSV55473336, COSV99849807; called by muse, mutect2, varscan2
- KMT2E | c.3600C>T p.A1200= | Silent (SNP) | VAF 9/40 reads (23%) | catalogued as rs913857764, COSV57573406, COSV57573432; called by muse, mutect2, varscan2
- MAML2 | c.1572G>T p.G524= | Silent (SNP) | VAF 14/39 reads (36%) | catalogued as COSV73263490; called by muse, mutect2, varscan2
- OR2AG2 | c.498C>T p.L166= | Silent (SNP) | VAF 20/72 reads (28%) | catalogued as COSV58455172; called by muse, mutect2, varscan2
- PARVB | c.165C>T p.P55= | Silent (SNP) | VAF 9/18 reads (50%) | catalogued as rs369214399; called by muse, mutect2, varscan2
- PLAGL1 | c.9G>A p.T3= | Silent (SNP) | VAF 18/72 reads (25%) | catalogued as rs539999694, COSV61334159; called by muse, mutect2, varscan2
- PRAMEF12 | c.1179G>T p.L393= | Silent (SNP) | VAF 72/153 reads (47%) | catalogued as rs775731012, COSV63215330; called by muse, mutect2
- PTPRA | c.1743G>A p.R581= | Silent (SNP) | VAF 30/61 reads (49%) | catalogued as rs755220395, COSV53781746, COSV99399975; called by muse, mutect2, varscan2
- TMEM132B | c.885C>T p.D295= | Silent (SNP) | VAF 8/25 reads (32%) | catalogued as rs1280350676, COSV54754023; called by muse, mutect2, varscan2
- ZBTB41 | c.747C>T p.S249= | Silent (SNP) | VAF 51/151 reads (34%) | catalogued as rs774434938, COSV66359171; called by muse, mutect2, varscan2
- HSPG2 | c.575-631C>T | Intron (SNP) | VAF 5/26 reads (19%) | catalogued as rs374750850; called by muse, mutect2, varscan2
- MDFIC | c.-147A>G | 5'UTR (SNP) | VAF 8/21 reads (38%) | catalogued as COSV99995242; called by muse, mutect2, varscan2
- MIR19B1 | n.29T>G | RNA (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
